National Lung Screening Trial (NLST) participant 217248 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 62 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer.
- T1 (day 372): Negative screen, minor abnormalities not suspicious for lung cancer.
- T2 (day 756): Negative screen, no significant abnormalities.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer occurred after the screening years; study year of the first confirmed lung cancer: T4; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 1,619, study year T4. Site: lower lobe of lung (ICD-O-3 C34.3), determined from histology. Primary tumour location: right lower lobe. Histology: squamous cell carcinoma, NOS (ICD-O-3 8070/3). Grade: moderately differentiated (G2). Tumour size on pathology: 31 mm. AJCC 6th edition staging: stage IV (best stage, from clinical TNM); clinical T2 N2 M1 (stage IV); pathologic TX NX MX. AJCC 7th edition staging: stage IV; clinical T2a N2 M1a; pathologic TX NX MX. Summary stage: distant.

Follow-up
Last known free of lung cancer: day 1,619 (for ACRIN participants with lung cancer this field holds the diagnosis date).
